Somatic mutation profile of tumor specimen 0DRL17 from CCDI case PBCGUH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 5.3 years (1,918 days).
Specimen 0DRL17: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 190cb593-f05f-45f1-826e-9846c1798d5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRL1O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6428e11a-2740-4c79-9f4c-7356e8e99c9c

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Splice Site 2, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NIPBL | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 140/676 reads (21%) | catalogued as rs587784009, CS042837, COSV56965837; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLRX3 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 214/858 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs751236022, COSV58691613, COSV58694969; called by muse, mutect2, varscan2
- S1PR2 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 226/772 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs373228288; called by muse, mutect2, varscan2
- SCN3A | c.3697C>T p.R1233* | Nonsense Mutation (SNP) | VAF 115/1144 reads (10%) | catalogued as rs1553519938; called by muse, mutect2, varscan2
- STAG1 | c.2203G>A p.V735M | Missense Mutation (SNP) | VAF 107/345 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs773534068, COSV52612905, COSV99366874; called by muse, mutect2, varscan2
- CD274 | c.25T>C p.F9L | Missense Mutation (SNP) | VAF 48/1133 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- PLOD1 | c.975+1G>A p.X325_splice | Splice Site (SNP) | VAF 84/531 reads (16%) | called by muse, mutect2, varscan2
- ZNF623 | c.1468A>T p.S490C | Missense Mutation (SNP) | VAF 179/552 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- EZHIP | c.219C>G p.T73= | Silent (SNP) | VAF 457/478 reads (96%) | called by muse, mutect2, varscan2
- OR4K3 | c.369C>T p.Y123= | Silent (SNP) | VAF 290/1166 reads (25%) | catalogued as rs1222631004; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/303 reads (4%) | called by muse, mutect2
